Somatic mutation profile of tumor specimen TCGA-BR-7196-01A (aliquot TCGA-BR-7196-01A-11D-2053-08) from TCGA case TCGA-BR-7196, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 64.6 years (23,611 days).
Specimen TCGA-BR-7196-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7de67d7c-b16d-4fcc-8cb6-6bdb00153ec3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-7196-10A (Blood Derived Normal), aliquot TCGA-BR-7196-10A-01D-2053-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e650236-c531-41c8-9992-f978fc3c4bff

The open-access MAF lists 67 somatic variants for this specimen: 54 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 12, Nonsense Mutation 8, Frame Shift Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV99288036; called by muse, mutect2
- ADAMTS20 | c.4874A>C p.K1625T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV101239055, COSV67135625; called by muse, mutect2
- AHNAK2 | c.6641C>T p.A2214V | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs751451433, COSV60922861; called by muse, mutect2
- AMER3 | c.1191G>C p.E397D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.207); catalogued as COSV58468511; called by muse, mutect2, varscan2
- ARID1A | c.3283C>T p.Q1095* | Nonsense Mutation (SNP) | VAF 10/75 reads (13%) | catalogued as COSV61378702; called by muse, mutect2, varscan2
- BCAS3 | c.2195C>T p.T732I (on ENST00000390652 / NM_001353144.2; = p.T717I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.82); catalogued as rs761349378, COSV66778254; called by muse, mutect2, varscan2
- BCL7C | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV53064055; called by muse, mutect2, varscan2
- BCOR | c.3487C>T p.R1163* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as COSV60713352; called by muse, mutect2, varscan2
- BDNF | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1048221, COSV59237026; called by muse, mutect2, varscan2
- CCDC171 | c.3731G>A p.R1244H | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs1446590594, COSV66242080; called by muse, mutect2, varscan2
- CD163 | c.666G>C p.W222C | Missense Mutation (SNP) | VAF 17/203 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63135385; called by muse, mutect2
- CEACAM5 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.039); catalogued as rs782807202, COSV55752130; called by muse, mutect2, varscan2
- CTNND1 | c.2009C>A p.S670* (on ENST00000399050 / NM_001085458.2; = p.S664* on NM_001331.3) | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | catalogued as COSV62384976, COSV62385365; called by muse, mutect2
- CYP2S1 | c.335A>T p.D112V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.059); catalogued as COSV59506849; called by muse, mutect2
- DHPS | c.518A>T p.N173I | Missense Mutation (SNP) | VAF 43/219 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52952742; called by muse, mutect2, varscan2
- DNAH5 | c.13368C>A p.F4456L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV99446000; called by muse, mutect2
- DYRK1A | c.1477G>A p.V493I | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1399540497, COSV58295654; called by muse, mutect2, varscan2
- ESR1 | c.1781C>T p.T594M | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as rs138891155; called by muse, mutect2, varscan2
- EXO1 | c.2153A>T p.Q718L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV62218678; called by muse, mutect2, varscan2
- FNDC1 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs776548524, COSV51943574; called by muse, mutect2, varscan2
- GUCY1A1 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV56654057; called by muse, mutect2, varscan2
- HCN1 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 5/41 reads (12%) | catalogued as COSV57525598; called by mutect2, varscan2
- HSP90AA1 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV53490196; called by muse, mutect2
- KIR2DL4 | c.1177G>A p.G393R (on ENST00000396284; = p.G319R on NM_001080770.2) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs777751353; called by muse, mutect2, varscan2
- LRRC1 | c.1396G>A p.D466N | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as rs1349763623, COSV63830005; called by muse, mutect2, varscan2
- MIB1 | c.2968A>T p.S990C | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs763759712, COSV55092798; called by muse, mutect2, varscan2
- MYC | c.1150T>G p.L384V (on ENST00000377970; = p.L399V on NM_002467.6) | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as COSV52376397; called by muse, mutect2
- MYLK | c.2627G>A p.R876H | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as rs537224715, COSV60616251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO3A | c.4489C>T p.R1497W | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); catalogued as rs886046926, COSV56320458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- P3H2 | c.1651A>C p.T551P | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60024925; called by muse, mutect2, varscan2
- PANK1 | c.787G>T p.E263* (on ENST00000307534 / NM_148977.2; = p.E38* on NM_138316.4) | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV56809446; called by muse, mutect2
- PCDHB2 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.341); catalogued as COSV99164296; called by muse, mutect2, varscan2
- PPAT | c.59C>G p.S20* | Nonsense Mutation (SNP) | VAF 24/195 reads (12%) | catalogued as COSV51705671; called by muse, mutect2, varscan2
- PPP6C | c.286C>T p.L96F | Missense Mutation (SNP) | VAF 19/189 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65208542; called by muse, mutect2, varscan2
- PTGER4 | c.1237A>C p.N413H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.36); catalogued as COSV56721931; called by muse, mutect2, varscan2
- RAPGEF4 | c.2675T>A p.F892Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.154); catalogued as COSV51404571; called by muse, mutect2, varscan2
- RNF167 | c.1044C>G p.I348M | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52591626; called by muse, mutect2
- SLITRK5 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV61524680; called by muse, mutect2
- TEP1 | c.3484A>G p.R1162G | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV52996428; called by muse, mutect2, varscan2
- TRIML2 | c.1167G>T p.M389I | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58718133, COSV58720293; called by muse, mutect2
- TRPC3 | c.2654C>A p.S885Y (on ENST00000379645 / NM_001366479.2; = p.S812Y on NM_003305.2) | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53378419; called by muse, mutect2, varscan2
- TTBK1 | c.3050G>A p.G1017D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.013); catalogued as COSV52494270; called by muse, mutect2, varscan2
- TUBA3E | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 26/188 reads (14%) | catalogued as rs746193667, COSV56059487; called by muse, varscan2
- USP48 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV57612509; called by muse, mutect2, varscan2
- WDPCP | c.995C>G p.T332S | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55426588; called by muse, mutect2
- WNK1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV60040094; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 16/150 reads (11%) | catalogued as rs745648385; called by mutect2, varscan2
- ZBTB33 | c.1753C>G p.R585G | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.354); catalogued as COSV58533600, COSV58534599; called by muse, mutect2
- ZMIZ2 | c.692C>G p.P231R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.13); catalogued as COSV54809793; called by muse, mutect2
- IGKV2D-24 | c.139C>A p.Q47K | Missense Mutation (SNP) | VAF 13/154 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- PRKCA | c.822-2_843del p.X274_splice | Splice Site (DEL) | VAF 8/58 reads (14%) | called by mutect2, pindel
- SIK3 | c.486del p.F163Sfs*21 (on ENST00000445177 / NM_001366686.2; = p.F169Sfs*21 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 15/151 reads (10%) | called by mutect2, pindel, varscan2
- ZNF81 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- ARMC5 | c.1683G>A p.P561= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs776009303, COSV51657062; ClinVar: likely benign; called by muse, mutect2, varscan2
- BDH1 | c.948C>T p.H316= | Silent (SNP) | VAF 62/256 reads (24%) | catalogued as COSV64019216; called by muse, mutect2, varscan2
- CAMKK1 | c.378C>T p.N126= | Silent (SNP) | VAF 14/238 reads (6%) | catalogued as COSV50121886; called by muse, mutect2
- CCDC60 | c.543C>T p.T181= | Silent (SNP) | VAF 23/136 reads (17%) | catalogued as rs1193249925, COSV59547475; called by muse, mutect2, varscan2
- FHOD3 | c.3912G>A p.A1304= (on ENST00000359247 / NM_001281739.3; = p.A1321= on NM_025135.5) | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs1374126094, COSV57181258; called by muse, mutect2, varscan2
- IPO11 | c.2526T>A p.P842= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV57579000; called by muse, mutect2, varscan2
- MYBPC2 | c.2154T>C p.A718= | Silent (SNP) | VAF 42/263 reads (16%) | catalogued as COSV63097939; called by muse, mutect2, varscan2
- NIPSNAP1 | c.657C>T p.G219= | Silent (SNP) | VAF 29/277 reads (10%) | catalogued as rs374371911, COSV53343407; called by muse, mutect2
- PRDM1 | c.1473G>A p.A491= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs747183412, COSV64846091; called by muse, mutect2, varscan2
- ROS1 | c.5883A>G p.E1961= | Silent (SNP) | VAF 14/160 reads (9%) | catalogued as COSV63858762; called by muse, mutect2
- VWC2L | c.57C>T p.V19= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as COSV56975112; called by muse, mutect2
- ZNF221 | c.816T>C p.H272= | Silent (SNP) | VAF 37/248 reads (15%) | catalogued as rs1183525827, COSV52110410; called by muse, mutect2, varscan2
- LCMT1 | c.114-2441C>G | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2, varscan2
